Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4279, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4279-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Stomach Tumor size: 5 x 4.5 x 1 cm Tumor features: None specified
Histologic type: Signet ring cell carcinoma Histologic grade: Poorly differentiated Tumor extent: Muscularis propria Lymph nodes: 3/6
positive for metastasis (Perigastric 3/6) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified
Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 551e818c-a271-4a0c-9017-34ed512e4d4f (TCGA-BR-4279.F6A3F144-BA0B-4195-9B3B-68DB9086C475.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).